Somatic mutation profile of tumor specimen C3L-01861-03 (aliquot CPT0092300009) from CPTAC case C3L-01861, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 57.4 years (20,974 days).
Specimen C3L-01861-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fccb717-1a66-4492-b08b-202e0b721282.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01861-31 (Blood Derived Normal), aliquot CPT0093770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa78ea5d-3970-4315-8c0a-0bd636a4f4f3

The open-access MAF lists 65 somatic variants for this specimen: 44 protein-altering or splice-affecting, 8 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Intron 8, Frame Shift Del 7, 3'UTR 3, Frame Shift Ins 3, In Frame Del 2, 5'UTR 1, Nonsense Mutation 1, Splice Site 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.4240C>T p.Q1414* (on ENST00000372530 / NM_001198934.2; = p.Q1386* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/160 reads (19%) | catalogued as rs759919213; called by muse, mutect2, varscan2
- FAM71B | c.52A>G p.M18V | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs763029396, COSV100262263; called by muse, mutect2, varscan2
- HDAC9 | c.2370-2A>G p.X790_splice | Splice Site (SNP) | VAF 10/66 reads (15%) | catalogued as COSV67783797; called by muse, mutect2, varscan2
- ID2 | c.24G>C p.R8S | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV52170176; called by muse, mutect2, varscan2
- MAP1B | c.6850G>C p.V2284L | Missense Mutation (SNP) | VAF 59/337 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs1156555263; called by muse, mutect2, varscan2
- NLRC3 | c.977G>A p.C326Y | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs369331984; called by muse, mutect2
- SEMA3A | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1353490966; called by muse, mutect2, varscan2
- TXNDC11 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1252420989; called by muse, mutect2, varscan2
- USH2A | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as rs754523763, COSV56403480; called by muse, mutect2, varscan2
- ZNF229 | c.1801G>A p.V601M | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs372929381; called by muse, mutect2, varscan2
- ZNF337 | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53323393; called by muse, mutect2, varscan2
- AL035460.1 | c.209C>A p.P70Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- CCDC168 | c.1718G>C p.G573A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CEP78 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CHRNG | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 70/374 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRNKL1 | c.2259G>A p.M753I | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CWC25 | c.416dup p.F140Lfs*17 | Frame Shift Ins (INS) | VAF 28/142 reads (20%) | called by mutect2, pindel
- DDX43 | c.1065_1066insT p.D356* | Frame Shift Ins (INS) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- DMXL2 | c.3619A>G p.S1207G | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC8 | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FTH1 | c.115-6T>G | Splice Region (SNP) | VAF 133/584 reads (23%) | called by muse, mutect2, varscan2
- ID2 | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, varscan2
- IRS2 | c.1760T>C p.V587A | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIRREL3 | c.1621del p.A541Pfs*2 | Frame Shift Del (DEL) | VAF 38/203 reads (19%) | called by mutect2, pindel, varscan2
- LARP1B | c.457dup p.R153Kfs*19 | Frame Shift Ins (INS) | VAF 59/323 reads (18%) | called by mutect2, pindel, varscan2
- LILRB1 | c.225del p.T76Pfs*6 (on ENST00000427581; = p.T40Pfs*6 on NM_006669.6) | Frame Shift Del (DEL) | VAF 29/188 reads (15%) | called by mutect2, pindel, varscan2
- LRRC10 | c.294del p.K98Nfs*20 | Frame Shift Del (DEL) | VAF 59/328 reads (18%) | called by mutect2, pindel, varscan2
- MLC1 | c.443T>A p.L148Q | Missense Mutation (SNP) | VAF 91/527 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MOB3A | c.287del p.K96Sfs*27 | Frame Shift Del (DEL) | VAF 47/317 reads (15%) | called by mutect2, pindel, varscan2
- PARP16 | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PBRM1 | c.2614_2625del p.F872_I875del | In Frame Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- PDCD6IP | c.31A>G p.K11E | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- PIEZO2 | c.2419T>C p.Y807H | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PKD2L2 | c.1679A>C p.Q560P | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- POGLUT3 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- RECQL | c.1670A>C p.E557A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RHBDL3 | c.1010_1016del p.H337Pfs*20 | Frame Shift Del (DEL) | VAF 79/327 reads (24%) | called by mutect2, pindel, varscan2
- ROCK2 | c.1704T>A p.N568K | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2
- SHANK2 | c.5225G>A p.S1742N | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- SUMO2 | c.236A>T p.E79V | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SUPT6H | c.1224C>G p.I408M | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- VHL | c.168del p.R58Gfs*9 | Frame Shift Del (DEL) | VAF 69/305 reads (23%) | called by mutect2, pindel, varscan2
- XKR6 | c.515_529del p.P172_V176del | In Frame Del (DEL) | VAF 68/351 reads (19%) | called by mutect2, varscan2
- ZNF462 | c.3711_3726del p.C1237* | Frame Shift Del (DEL) | VAF 38/214 reads (18%) | called by mutect2, pindel, varscan2
- F12 | c.495T>A p.G165= | Silent (SNP) | VAF 125/704 reads (18%) | called by muse, mutect2, varscan2
- LRP2 | c.6381T>A p.I2127= | Silent (SNP) | VAF 46/242 reads (19%) | called by muse, mutect2, varscan2
- LRP2 | c.6246T>C p.D2082= | Silent (SNP) | VAF 62/291 reads (21%) | called by muse, mutect2, varscan2
- MAP2K3 | c.720G>A p.L240= (on ENST00000342679 / NM_145109.3; = p.L211= on NM_002756.4) | Silent (SNP) | VAF 54/581 reads (9%) | catalogued as COSV57567395; called by muse, mutect2
- SLC10A7 | c.615C>A p.I205= | Silent (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2
- SNX5 | c.654C>T p.N218= | Silent (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- TEDDM1 | c.798C>G p.L266= | Silent (SNP) | VAF 32/179 reads (18%) | called by muse, mutect2
- YOD1 | c.102G>A p.A34= | Silent (SNP) | VAF 37/196 reads (19%) | called by muse, mutect2, varscan2
- CABIN1 | c.4117+31C>T | Intron (SNP) | VAF 60/353 reads (17%) | catalogued as rs754732045; called by muse, mutect2, varscan2
- CHD3 | c.5591-54T>G | Intron (SNP) | VAF 43/264 reads (16%) | called by muse, mutect2, varscan2
- LMOD1 | c.*19C>G | 3'UTR (SNP) | VAF 31/256 reads (12%) | called by muse, mutect2, varscan2
- LMOD1 | c.*18C>T | 3'UTR (SNP) | VAF 31/252 reads (12%) | catalogued as rs766264807; called by muse, mutect2, varscan2
- MTMR14 | c.-6T>C | 5'UTR (SNP) | VAF 34/171 reads (20%) | called by muse, mutect2, varscan2
- MTMR14 | c.1770-30T>G | Intron (SNP) | VAF 73/354 reads (21%) | called by muse, mutect2, varscan2
- NAP1L1 | c.1089+234T>A | Intron (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- NDUFA10 | c.999+6363G>C | Intron (SNP) | VAF 44/196 reads (22%) | catalogued as rs1559353296; called by muse, mutect2, varscan2
- SEC14L2 | c.55-902C>A | Intron (SNP) | VAF 22/153 reads (14%) | called by muse, mutect2, varscan2
- SLC25A13 | c.*226T>C | 3'UTR (SNP) | VAF 36/382 reads (9%) | catalogued as rs1320616847; called by muse, mutect2
- ST6GALNAC2 | chr17:76561186 A>G | 3'Flank (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+2771A>T | Intron (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- TNNT1 | c.129-12C>G | Intron (SNP) | VAF 54/298 reads (18%) | called by muse, mutect2, varscan2
